Somatic mutation profile of tumor specimen C3L-00589-01 (aliquot CPT0063970007) from CPTAC case C3L-00589, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 80.3 years (29,322 days).
Specimen C3L-00589-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eb1a449c-78ad-49c1-a1d5-1af964f60a97.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00589-31 (Blood Derived Normal), aliquot CPT0065360002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c1c91db4-2a00-42ca-9043-d1781d999287

The open-access MAF lists 99 somatic variants for this specimen: 69 protein-altering or splice-affecting, 20 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 20, Frame Shift Del 4, Nonsense Mutation 3, RNA 3, Frame Shift Ins 2, Intron 2, 5'Flank 2, In Frame Del 1, 3'Flank 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 33/158 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PDYN | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 20/316 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201486601, CM107860, COSV54101259; ClinVar: pathogenic; called by muse, mutect2
- TNR | c.2713C>T p.R905* | Nonsense Mutation (SNP) | VAF 8/116 reads (7%) | catalogued as rs1287757170, COSV99687070; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.464C>A p.T155N | Missense Mutation (SNP) | VAF 86/416 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as rs786202752, CM942117, HM090066, COSV52692291, COSV52711720, COSV52741190, COSV52782333; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADAMTS10 | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 46/578 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as COSV54357422; called by muse, mutect2
- ADCY8 | c.2903G>A p.R968Q | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as rs374456387; called by muse, mutect2
- AFF2 | c.810C>G p.F270L | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60681163; called by muse, mutect2, varscan2
- ANKK1 | c.2246C>T p.P749L | Missense Mutation (SNP) | VAF 15/156 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as rs775477797; called by muse, mutect2
- CCDC154 | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 74/892 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.056); catalogued as rs113602113; called by muse, mutect2
- CHPF | c.703G>A p.G235R | Missense Mutation (SNP) | VAF 23/245 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as rs1336922788, COSV60535208; called by muse, mutect2
- COL1A1 | c.1108C>T p.R370C | Missense Mutation (SNP) | VAF 36/432 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs758897245, COSV56802381; called by muse, mutect2
- COL22A1 | c.145G>A p.V49M | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1254490670, COSV57351511; called by muse, mutect2
- COL6A1 | c.2030G>A p.R677H | Missense Mutation (SNP) | VAF 78/762 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs373731596; called by muse, mutect2, varscan2
- CTNNA2 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs377364195; called by mutect2, varscan2
- GHRHR | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 28/324 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.949); catalogued as rs200472991, COSV58197595; ClinVar: uncertain significance; called by muse, mutect2
- GPRC5B | c.670G>A p.G224S | Missense Mutation (SNP) | VAF 44/570 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs148789431; called by muse, mutect2
- GRIK4 | c.1706C>T p.T569M | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs373630796; called by muse, mutect2, varscan2
- GSDMA | c.176C>T p.T59M | Missense Mutation (SNP) | VAF 58/1066 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs754816059, COSV56977327; called by muse, mutect2
- HEY2 | c.644C>T p.T215I | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs1316943640; called by muse, mutect2
- KCTD11 | c.602G>A p.R201H (on ENST00000333751 / NM_001363642.1; = p.R162H on NM_001002914.2) | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as rs865964999, COSV50134200; called by muse, mutect2
- LDLRAD3 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 21/250 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100214374; called by muse, mutect2
- MACROD2 | c.353del p.R118Lfs*3 | Frame Shift Del (DEL) | VAF 17/130 reads (13%) | catalogued as COSV54026962; called by mutect2, pindel, varscan2
- MEX3D | c.1078G>A p.D360N | Missense Mutation (SNP) | VAF 46/271 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.451); catalogued as COSV101183472; called by muse, mutect2, varscan2
- NGEF | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 26/237 reads (11%) | SIFT tolerated (0.98); PolyPhen benign (0.001); catalogued as rs765885436, COSV50916867; called by muse, mutect2
- NINL | c.2105G>A p.R702H | Missense Mutation (SNP) | VAF 11/178 reads (6%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs917252420; called by muse, mutect2
- NOS1AP | c.1141C>T p.R381C | Missense Mutation (SNP) | VAF 37/507 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as COSV62633557; called by muse, mutect2
- NPTX2 | c.985G>A p.G329R | Missense Mutation (SNP) | VAF 28/342 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375252857; called by muse, mutect2
- OR6F1 | c.872C>T p.T291M | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.14); catalogued as rs186143987, COSV57467500; called by muse, mutect2
- PKD1 | c.3602C>T p.A1201V | Missense Mutation (SNP) | VAF 97/1364 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.021); catalogued as rs773471530, CM143939; called by muse, mutect2
- PPP1R10 | c.2033C>T p.P678L | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1405225650; called by muse, mutect2
- PRKX | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.705); catalogued as rs751998171; called by muse, mutect2, varscan2
- PTPRF | c.1172C>T p.A391V | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as rs746910917, COSV63447231; called by muse, mutect2
- RASGEF1A | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 34/492 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs767084570, COSV65666676; called by muse, mutect2
- RP1 | c.2153A>G p.D718G | Missense Mutation (SNP) | VAF 14/151 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs1465609803; called by muse, mutect2
- SETBP1 | c.1799C>T p.T600M | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1201997891, COSV56322690; called by muse, mutect2
- SLC22A12 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 60/704 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs141975942; called by muse, mutect2
- SORCS2 | c.2968C>T p.R990W | Missense Mutation (SNP) | VAF 15/210 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.902); catalogued as rs375771681; called by muse, mutect2
- TRIM72 | c.169C>T p.Q57* | Nonsense Mutation (SNP) | VAF 68/319 reads (21%) | catalogued as rs1356384611; called by muse, mutect2, varscan2
- UNC79 | c.4183C>T p.R1395W (on ENST00000393151 / NM_001346218.2; = p.R1218W on NM_020818.5) | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769549721, COSV56378995; called by muse, mutect2, varscan2
- ZBTB17 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 51/609 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs757761976, COSV100998986; called by muse, mutect2
- ABCE1 | c.280_283del p.L94Tfs*14 | Frame Shift Del (DEL) | VAF 12/107 reads (11%) | called by mutect2, pindel
- AXIN2 | c.777_778insGG p.S260Gfs*3 | Frame Shift Ins (INS) | VAF 35/223 reads (16%) | called by mutect2, pindel, varscan2
- BRF1 | c.1340T>A p.L447Q | Missense Mutation (SNP) | VAF 18/263 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); called by muse, mutect2
- CALM1 | c.121G>A p.G41S | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CSMD1 | c.10387T>C p.F3463L (on ENST00000520002; = p.F3462L on NM_033225.6) | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- DMXL1 | c.3159_3160del p.T1054Kfs*8 | Frame Shift Del (DEL) | VAF 9/106 reads (8%) | called by mutect2, pindel
- FAT4 | c.13769A>C p.N4590T | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.986); called by muse, mutect2
- G6PD | c.1248_1249del p.E417Vfs*18 | Frame Shift Del (DEL) | VAF 80/477 reads (17%) | called by mutect2, pindel, varscan2
- GAS7 | c.85A>G p.I29V | Missense Mutation (SNP) | VAF 64/746 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2
- GHRH | c.34A>G p.T12A | Missense Mutation (SNP) | VAF 19/206 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.621); called by muse, mutect2
- KCNS1 | c.370C>T p.H124Y | Missense Mutation (SNP) | VAF 26/284 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); called by muse, mutect2
- KCNV1 | c.289G>A p.V97M | Missense Mutation (SNP) | VAF 77/763 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KMT2C | c.10772A>G p.Q3591R | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); called by muse, mutect2
- LRRC9 | c.4037C>G p.P1346R | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); called by muse, mutect2, varscan2
- MN1 | c.2621C>T p.P874L | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2
- OR10G9 | c.595T>C p.F199L | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PAGR1 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 21/386 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- PCNX1 | c.581G>T p.C194F | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); called by muse, mutect2
- PIK3R6 | c.241A>T p.M81L | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2
- PNLIPRP2 | c.1123A>G p.R375G (on ENST00000611850; = p.R376G on NM_005396.5) | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PTPRO | c.596C>G p.T199S | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); called by muse, mutect2
- SLC34A2 | c.1522_1527del p.T508_R509del | In Frame Del (DEL) | VAF 64/504 reads (13%) | called by mutect2, pindel
- STARD9 | c.8195T>A p.V2732D | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNS4 | c.2132A>T p.D711V | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2
- TRAF3IP3 | c.937C>T p.Q313* | Nonsense Mutation (SNP) | VAF 40/145 reads (28%) | called by muse, mutect2, varscan2
- TTN | c.75057dup p.Y25020Ifs*4 (on ENST00000591111; = p.Y17596Ifs*4 on NM_003319.4) | Frame Shift Ins (INS) | VAF 15/106 reads (14%) | called by mutect2, pindel, varscan2
- WDR47 | c.1727G>T p.G576V (on ENST00000369962 / NM_001142551.2; = p.G577V on NM_014969.5) | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.01); called by muse, mutect2
- ZFPM1 | c.1041C>T p.S347= | Splice Region (SNP) | VAF 27/366 reads (7%) | called by muse, mutect2
- ZNF551 | c.1084C>G p.P362A | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); called by muse, mutect2
- ACTN2 | c.1392C>T p.I464= | Silent (SNP) | VAF 35/486 reads (7%) | catalogued as rs764086805, COSV63971447, COSV63972072; ClinVar: likely benign; called by muse, mutect2
- ADAMTS13 | c.1911G>T p.L637= | Silent (SNP) | VAF 34/344 reads (10%) | called by muse, mutect2
- BICDL2 | c.354C>T p.A118= | Silent (SNP) | VAF 40/509 reads (8%) | catalogued as rs1433439192; called by muse, mutect2
- C5AR2 | c.9C>T p.N3= | Silent (SNP) | VAF 25/383 reads (7%) | catalogued as rs1430628557, COSV57256903; called by muse, mutect2
- CDC20B | c.1095G>A p.P365= | Silent (SNP) | VAF 34/331 reads (10%) | catalogued as rs375917242; called by muse, mutect2, varscan2
- CXorf58 | c.606C>T p.N202= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs372466657, COSV64858132; called by muse, mutect2
- DMRT3 | c.264C>T p.P88= | Silent (SNP) | VAF 18/153 reads (12%) | called by muse, mutect2, varscan2
- ECEL1 | c.1212C>T p.R404= | Silent (SNP) | VAF 36/239 reads (15%) | catalogued as rs764036925, COSV58812069; called by muse, mutect2, varscan2
- FAM187B | c.369G>A p.L123= | Silent (SNP) | VAF 34/361 reads (9%) | catalogued as rs1375864874; called by muse, mutect2
- MAP4K4 | c.1131G>A p.Q377= | Silent (SNP) | VAF 30/183 reads (16%) | called by muse, mutect2, varscan2
- MYO16 | c.4152G>A p.A1384= | Silent (SNP) | VAF 28/326 reads (9%) | called by muse, mutect2
- NAALADL1 | c.1152C>T p.A384= | Silent (SNP) | VAF 20/223 reads (9%) | catalogued as rs368997186; called by muse, mutect2
- NCAM1 | c.1803C>T p.S601= (on ENST00000316851 / NM_181351.5; = p.S591= on NM_000615.7) | Silent (SNP) | VAF 13/247 reads (5%) | catalogued as rs536431053, COSV57516384; called by muse, mutect2
- OBSL1 | c.3915C>T p.D1305= | Silent (SNP) | VAF 28/285 reads (10%) | catalogued as rs926056344; called by muse, mutect2, varscan2
- PTPN3 | c.1848C>T p.P616= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as rs756050290, COSV99355862; called by muse, mutect2, varscan2
- RFX1 | c.879C>T p.S293= | Silent (SNP) | VAF 18/260 reads (7%) | catalogued as rs951951549, COSV54334046; called by muse, mutect2
- RGL2 | c.78G>C p.R26= | Silent (SNP) | VAF 6/92 reads (7%) | called by muse, mutect2
- RIMBP2 | c.2115C>T p.D705= | Silent (SNP) | VAF 61/372 reads (16%) | catalogued as rs761677291, COSV55467808; called by muse, mutect2, varscan2
- TTBK2 | c.1278C>T p.V426= | Silent (SNP) | VAF 17/280 reads (6%) | catalogued as rs1490347590; called by muse, mutect2
- UBAC1 | c.480C>T p.I160= | Silent (SNP) | VAF 16/202 reads (8%) | catalogued as rs1248931704; called by muse, mutect2
- ADAM19 | chr5:157480971 C>A | 3'Flank (SNP) | VAF 8/171 reads (5%) | called by muse, mutect2
- CCDC187 | c.*2698C>T | 3'UTR (SNP) | VAF 10/148 reads (7%) | catalogued as rs1055911551; called by muse, mutect2
- FAM183BP | n.612C>T | RNA (SNP) | VAF 14/168 reads (8%) | called by muse, mutect2
- GLRXP3 | n.85G>A | RNA (SNP) | VAF 22/166 reads (13%) | called by muse, mutect2, varscan2
- NRG1 | chr8:31639417 G>A | 5'Flank (SNP) | VAF 55/550 reads (10%) | catalogued as rs777329120; called by muse, mutect2
- PPP1R9A | c.2757+552A>T | Intron (SNP) | VAF 6/130 reads (5%) | called by muse, mutect2
- PSPN | chr19:6375850 T>A | 5'Flank (SNP) | VAF 48/586 reads (8%) | called by muse, mutect2
- PTPRS | c.-25C>T | 5'UTR (SNP) | VAF 23/290 reads (8%) | catalogued as rs1295173495; called by muse, mutect2
- SLC25A51P4 | n.827G>A | RNA (SNP) | VAF 17/164 reads (10%) | catalogued as rs761032308; called by muse, mutect2
- UBXN2B | c.533+356T>C | Intron (SNP) | VAF 10/95 reads (11%) | called by muse, mutect2
